Somatic mutation profile of tumor specimen MP2PRT-PAVPNL-TMP1-A (aliquot MP2PRT-PAVPNL-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVPNL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (821 days).
Specimen MP2PRT-PAVPNL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e016edb-c0ed-4920-b9a4-061f513dedc3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVPNL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVPNL-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05ae0cee-ef90-4c57-9bc8-89d45ece030d

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EDAR | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 108/447 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs138052931, COSV99304406; called by muse, mutect2, varscan2
- KLHL32 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 34/430 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs1562353209, COSV65115583; called by muse, mutect2
- NCAPD3 | c.4448C>T p.A1483V | Missense Mutation (SNP) | VAF 111/400 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs561577155; called by muse, mutect2, varscan2
- NDNF | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 132/424 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs372865079, COSV101113188, COSV65632616; called by muse, mutect2, varscan2
- RTN2 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 146/477 reads (31%) | catalogued as COSV55592575; called by muse, mutect2, varscan2
- ST6GAL2 | c.43G>A p.G15R | Missense Mutation (SNP) | VAF 114/403 reads (28%) | PolyPhen probably damaging (0.969); catalogued as COSV64528036; called by muse, mutect2, varscan2
- SCARA5 | c.1181G>A p.R394H | Missense Mutation (SNP) | VAF 185/608 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA6D | c.478A>T p.I160F | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.38); called by muse, mutect2
- WNT10A | c.1213_1214insCCGACCC p.E405Afs*25 | Frame Shift Ins (INS) | VAF 140/633 reads (22%) | called by mutect2, pindel, varscan2
- IGKV1D-8 | c.352_353insA p.*118H | Silent (INS) | VAF 27/56 reads (48%) | called by mutect2, pindel*, varscan2
